Somatic mutation profile of tumor specimen TARGET-10-PARBND-09A (aliquot TARGET-10-PARBND-09A-01D) from TARGET case TARGET-10-PARBND, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.2 years (1,539 days).
Specimen TARGET-10-PARBND-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 232121c3-3b22-4cd3-a6c5-f76243d01216.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PARBND-10A (Blood Derived Normal), aliquot TARGET-10-PARBND-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2080860f-213e-40a4-9214-afdbfafc0d14

The open-access MAF lists 35 somatic variants for this specimen: 19 protein-altering or splice-affecting, 9 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 17, Silent 9, Intron 3, RNA 2, 3'Flank 2, Frame Shift Ins 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AP1G1 | c.2051C>T p.P684L | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as rs1217056627; called by muse, mutect2, varscan2
- DCAF8L2 | c.556C>T p.R186C | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.139); catalogued as COSV101446127; called by muse, mutect2
- EFHB | c.1085G>A p.R362Q | Missense Mutation (SNP) | VAF 35/67 reads (52%) | SIFT tolerated (0.18); PolyPhen benign (0.015); catalogued as rs770547449; called by muse, mutect2, varscan2
- FAM9B | c.5C>T p.A2V | Missense Mutation (SNP) | VAF 29/100 reads (29%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.75); catalogued as COSV59119225; called by muse, mutect2, varscan2
- GRID2 | c.799G>A p.D267N | Missense Mutation (SNP) | VAF 61/196 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as rs765119459, COSV56221182, COSV56283981; called by muse, mutect2, varscan2
- HLA-DRA | c.553G>A p.V185I | Missense Mutation (SNP) | VAF 33/80 reads (41%) | SIFT tolerated (0.35); PolyPhen benign (0.001); catalogued as rs200798853, COSV100895091; called by muse, mutect2, varscan2
- IL20RA | c.683G>A p.R228H | Missense Mutation (SNP) | VAF 39/103 reads (38%) | SIFT tolerated (0.56); PolyPhen benign (0.015); catalogued as rs747471948, COSV57356711; called by muse, mutect2, varscan2
- MDC1 | c.5771C>T p.S1924F | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV64525082; called by muse, mutect2, varscan2
- MITF | c.242C>T p.A81V | Missense Mutation (SNP) | VAF 23/59 reads (39%) | SIFT tolerated (0.21); PolyPhen benign (0.213); catalogued as rs781567478, COSV58884038; called by muse, mutect2, varscan2
- SEPTIN12 | c.796C>T p.R266W | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs750089256, COSV51615663; called by muse, mutect2, varscan2
- CTTN | c.1344G>A p.M448I | Missense Mutation (SNP) | VAF 22/49 reads (45%) | SIFT tolerated (0.22); PolyPhen benign (0); called by muse, mutect2, varscan2
- EHMT2 | c.103_104insGCCTTCG p.E35Gfs*15 | Frame Shift Ins (INS) | VAF 14/52 reads (27%) | called by mutect2, varscan2
- JAKMIP1 | c.1546G>A p.E516K | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- KNL1 | c.3713C>T p.A1238V (on ENST00000346991 / NM_170589.5; = p.A1212V on NM_144508.5) | Missense Mutation (SNP) | VAF 74/189 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- NCKAP5 | c.3081C>A p.S1027R | Missense Mutation (SNP) | VAF 13/72 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.406); called by muse, mutect2, varscan2
- OR52E8 | c.708G>A p.W236* | Nonsense Mutation (SNP) | VAF 25/65 reads (38%) | called by muse, mutect2, varscan2
- PAK3 | c.283C>T p.L95F (on ENST00000262836 / NM_001324328.2; = p.L116F on NM_001128168.3) | Missense Mutation (SNP) | VAF 20/37 reads (54%) | SIFT tolerated, low confidence (0.41); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- SIGLEC6 | c.481C>T p.P161S | Missense Mutation (SNP) | VAF 31/66 reads (47%) | SIFT tolerated (0.14); PolyPhen benign (0.08); called by muse, mutect2, varscan2
- UNC13A | c.2881G>A p.E961K | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.146); called by muse, mutect2, varscan2
- AP1G1 | c.2052C>T p.P684= | Silent (SNP) | VAF 20/55 reads (36%) | called by muse, mutect2, varscan2
- ESRP1 | c.1392C>T p.F464= | Silent (SNP) | VAF 26/111 reads (23%) | catalogued as rs747030296; called by muse, mutect2, varscan2
- FHL5 | c.402A>G p.R134= | Silent (SNP) | VAF 21/147 reads (14%) | catalogued as COSV58739225; called by muse, mutect2, varscan2
- GPR107 | c.1767C>T p.S589= (on ENST00000372406 / NM_001136557.2; = p.S541= on NM_020960.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 18/77 reads (23%) | catalogued as rs781916436; called by muse, mutect2, varscan2
- MED12L | c.3456C>T p.F1152= | Silent (SNP) | VAF 30/89 reads (34%) | catalogued as COSV56376303; called by muse, mutect2, varscan2
- MYBPC3 | c.1941C>T p.I647= | Silent (SNP) | VAF 21/39 reads (54%) | called by muse, mutect2, varscan2
- OR2J2 | c.459T>A p.G153= | Silent (SNP) | VAF 66/138 reads (48%) | called by muse, mutect2
- SGO2 | c.1356C>T p.F452= | Silent (SNP) | VAF 51/114 reads (45%) | called by muse, mutect2, varscan2
- SSC5D | c.648C>T p.G216= | Silent (SNP) | VAF 6/35 reads (17%) | catalogued as rs764384051; called by muse, mutect2, varscan2
- CACYBPP2 | n.635G>C | RNA (SNP) | VAF 11/134 reads (8%) | called by muse, mutect2
- GPHN | c.1980+63C>T | Intron (SNP) | VAF 47/128 reads (37%) | called by muse, mutect2, varscan2
- IGHV5-51 | chr14:106578743 ins ACAGGGGGA | 3'Flank (INS) | VAF 14/38 reads (37%) | called by mutect2, pindel*, varscan2
- IGLV4-69 | chr22:22031472 ins TGAGC | 3'Flank (INS) | VAF 12/53 reads (23%) | called by pindel, varscan2
- KIDINS220 | c.3528+98C>T | Intron (SNP) | VAF 8/27 reads (30%) | called by muse, mutect2
- LINC01101 | n.443C>A | RNA (SNP) | VAF 32/89 reads (36%) | called by muse, mutect2, varscan2
- TIMP2 | c.465+92G>A | Intron (SNP) | VAF 14/30 reads (47%) | catalogued as rs762189041; called by muse, mutect2, varscan2
